Surgical pathology report (de-identified scan), TCGA case TCGA-R6-A6Y2, project TCGA-ESCA (Esophageal Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R6-A6Y2-01B (Primary Tumor).

Specimen Date/Time:

ICD-O-3
Adenocarcinoma NOS
8/40/3
Site Esophagus, distal third
C15.5
JW 8/8/13

DIAGNOSIS

- (A) STOMACH, LESSER CURVATURE ULCER SCAR, BIOPSY:
Gastric mucosa with focal active inflammation, fibrosis of the lamina propria and foveolar hyperplasia;
negative for carcinoma.
- (B) DISTAL ESOPHAGEAL TUMOR, BIOPSY:
INVASIVE ADENOCARCINOMA, MODERATELY TO POORLY DIFFERENTIATED.
COLUMNAR MUCOSA WITH HIGH GRADE DYSPLASIA.

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) ULCER, SCAR, LESSER CURVATURE - Multiple tan-pink irregular fragments of tissue (1.0 x 0.7 x 0.2 cm in aggregate).
Toto in A.
- (B) DISTAL ESOPHAGEAL TUMOR - Multiple tan-pink irregular fragments of tissue (1.3 x 0.7 x 0.2 cm in aggregate). Toto in B.

CLINICAL HISTORY

Esophageal cancer and Barrett esophagus.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by
specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 91112d52-6e6a-459d-a7cc-bd0a1d684caa (TCGA-R6-A6Y2.4E68B5A8-19BB-4D54-B503-493AF9146B19.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).